Somatic mutation profile of tumor specimen HCM-CSHL-0246-C19-86A (aliquot HCM-CSHL-0246-C19-86A-01D-A85C-36) from HCMI case HCM-CSHL-0246-C19, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Vital status: Alive; Primary diagnosis: Mucinous adenocarcinoma; Tissue or organ of origin: Rectum, NOS; AJCC pathologic stage: Stage IIIC; Tumor grade: GX; Age at diagnosis: 55.9 years (20,434 days).
Specimen HCM-CSHL-0246-C19-86A: Sample type: Expanded Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: 3D Organoid; Preservation method: Frozen; Passage count: 11.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 2f4de221-7ca7-4134-bd02-fc7ab107765e.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HCM-CSHL-0246-C19-10A (Blood Derived Normal), aliquot HCM-CSHL-0246-C19-10A-01D-A78L-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/95b77a5d-5b79-4078-8ed3-5efebcb58282

The open-access MAF lists 203 somatic variants for this specimen: 137 protein-altering or splice-affecting, 49 silent, 17 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 112, Silent 49, Nonsense Mutation 10, 5'UTR 7, Intron 6, Frame Shift Del 4, In Frame Del 3, Frame Shift Ins 3, Splice Site 3, Splice Region 2, RNA 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRAF | c.1919T>A p.V640E (on ENST00000288602 / NM_001374244.1; = p.V600E on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 105/115 reads (91%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs113488022, CM112509, COSV56056643, COSV56065204, COSV56080151; ClinVar: pathogenic / likely pathogenic / other / drug response; called by muse, mutect2, varscan2
- TP53 | c.589G>A p.V197M | Missense Mutation (SNP) | VAF 422/426 reads (99%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen probably damaging (0.961); catalogued as rs786204041, CM070297, COSV52711079, COSV52927251, COSV53163944; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ABCA12 | c.1435C>A p.L479M (on ENST00000272895 / NM_173076.3; = p.L161M on NM_015657.3) | Missense Mutation (SNP) | VAF 195/457 reads (43%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.923); catalogued as COSV99790843; called by muse, mutect2, varscan2
- ALX4 | c.472G>A p.E158K | Missense Mutation (SNP) | VAF 139/264 reads (53%) | SIFT deleterious (0.04); PolyPhen benign (0.014); catalogued as COSV61325932; called by muse, varscan2
- ARHGAP21 | c.5395C>T p.R1799W | Missense Mutation (SNP) | VAF 398/602 reads (66%) | SIFT tolerated (0.16); PolyPhen benign (0.062); catalogued as rs768755069, COSV100256513; called by muse, mutect2, varscan2
- ARHGAP22 | c.1944dup p.Y649Ifs*12 | Frame Shift Ins (INS) | VAF 136/506 reads (27%) | catalogued as rs1256821192; called by pindel, varscan2
- B3GALT4 | c.397G>A p.A133T | Missense Mutation (SNP) | VAF 386/881 reads (44%) | SIFT tolerated (0.29); PolyPhen benign (0.003); catalogued as rs765360254; called by muse, mutect2, varscan2
- BNC2 | c.1558C>T p.P520S | Missense Mutation (SNP) | VAF 405/406 reads (100%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.829); catalogued as rs1210859066; called by muse, mutect2, varscan2
- BPIFB2 | c.956G>A p.R319Q | Missense Mutation (SNP) | VAF 245/819 reads (30%) | SIFT tolerated (0.3); PolyPhen benign (0.013); catalogued as rs746477434; called by muse, mutect2, varscan2
- BRINP1 | c.1889G>A p.R630Q | Missense Mutation (SNP) | VAF 328/529 reads (62%) | SIFT tolerated (0.58); PolyPhen possibly damaging (0.456); catalogued as rs151087333, COSV56292314; called by muse, mutect2, varscan2
- CELSR1 | c.8960C>T p.P2987L | Missense Mutation (SNP) | VAF 281/614 reads (46%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.06); catalogued as rs866441078; called by muse, mutect2, varscan2
- CERK | c.673G>A p.V225M | Missense Mutation (SNP) | VAF 209/487 reads (43%) | SIFT tolerated (0.11); PolyPhen benign (0.103); catalogued as rs1337514286; called by muse, mutect2, varscan2
- CFAP47 | c.8137G>T p.A2713S | Missense Mutation (SNP) | VAF 112/201 reads (56%) | SIFT tolerated (0.07); PolyPhen benign (0.079); catalogued as COSV66216178; called by muse, mutect2, varscan2
- CHRM4 | c.358G>A p.V120I | Missense Mutation (SNP) | VAF 235/500 reads (47%) | SIFT deleterious (0); PolyPhen benign (0.241); catalogued as rs1247534212, COSV63127569; called by muse, mutect2, varscan2
- CKMT1B | c.1143G>C p.E381D | Missense Mutation (SNP) | VAF 132/504 reads (26%) | SIFT deleterious (0.04); PolyPhen benign (0.078); catalogued as COSV55852209; called by muse, mutect2, varscan2
- CNTN2 | c.125A>G p.Q42R | Missense Mutation (SNP) | VAF 218/473 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV59348607; called by muse, mutect2, varscan2
- CPQ | c.548C>T p.T183M | Missense Mutation (SNP) | VAF 171/397 reads (43%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.849); catalogued as rs577356141, COSV55138391; called by muse, mutect2, varscan2
- CST2 | c.301T>A p.L101M | Missense Mutation (SNP) | VAF 230/767 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV59031360; called by muse, mutect2, varscan2
- EPB41L3 | c.1777C>T p.P593S | Missense Mutation (SNP) | VAF 175/1858 reads (9%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.946); catalogued as rs1378114067; called by muse, mutect2
- FBN1 | c.4762C>A p.L1588I | Missense Mutation (SNP) | VAF 104/367 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV104413959, COSV57322943; called by muse, varscan2
- INO80C | c.379+2_379+3del p.X127_splice | Splice Site (DEL) | VAF 121/244 reads (50%) | catalogued as rs1323332387; called by pindel, varscan2
- KCNA3 | c.832G>A p.G278S | Missense Mutation (SNP) | VAF 262/585 reads (45%) | SIFT tolerated (0.53); PolyPhen benign (0.006); catalogued as rs1204573283, COSV100871279; called by muse, mutect2, varscan2
- KHDC3L | c.597C>A p.S199R | Missense Mutation (SNP) | VAF 216/511 reads (42%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV64859440; called by muse, mutect2, varscan2
- KLK6 | c.340C>T p.R114C | Missense Mutation (SNP) | VAF 450/998 reads (45%) | SIFT deleterious (0.02); PolyPhen benign (0.283); catalogued as rs200194649, COSV59565296; called by muse, mutect2, varscan2
- LRP1B | c.2446C>T p.R816W | Missense Mutation (SNP) | VAF 196/352 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs771071015, COSV67263162; called by muse, varscan2
- MAP2 | c.1567G>A p.E523K | Missense Mutation (SNP) | VAF 193/354 reads (55%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.838); catalogued as rs747788362; called by muse, mutect2, varscan2
- MYO3A | c.3232A>C p.I1078L | Missense Mutation (SNP) | VAF 170/564 reads (30%) | SIFT tolerated (0.98); PolyPhen benign (0); catalogued as COSV56322652; called by muse, varscan2
- NCKAP5L | c.3517G>A p.A1173T | Missense Mutation (SNP) | VAF 113/607 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.321); catalogued as rs766539226; called by muse, mutect2, varscan2
- NEB | c.4955C>A p.S1652* | Nonsense Mutation (SNP) | VAF 217/445 reads (49%) | catalogued as COSV50805867; called by muse, mutect2, varscan2
- NLRP4 | c.596C>T p.T199M | Missense Mutation (SNP) | VAF 452/940 reads (48%) | SIFT tolerated (0.06); PolyPhen benign (0.053); catalogued as rs370421219; called by muse, mutect2, varscan2
- OR2T2 | c.706C>T p.R236C | Missense Mutation (SNP) | VAF 244/815 reads (30%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.729); catalogued as rs200389028, COSV100737564; called by muse, mutect2, varscan2
- OR4E2 | c.163C>A p.L55I | Missense Mutation (SNP) | VAF 39/424 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0.422); catalogued as COSV57731979; called by muse, mutect2
- OR6N1 | c.660G>T p.Q220H | Missense Mutation (SNP) | VAF 18/457 reads (4%) | SIFT tolerated (0.27); PolyPhen possibly damaging (0.755); catalogued as rs1468988450, COSV58649270, COSV58650226; called by muse, mutect2
- PAXIP1 | c.719C>T p.T240I | Missense Mutation (SNP) | VAF 200/218 reads (92%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.439); catalogued as rs1444898194; called by muse, mutect2, varscan2
- PCDH15 | c.2273A>C p.N758T | Missense Mutation (SNP) | VAF 118/492 reads (24%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.949); catalogued as COSV100213990, COSV57278399; called by muse, mutect2, varscan2
- PDE1B | c.1180C>T p.R394C | Missense Mutation (SNP) | VAF 53/296 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs958466168, COSV54490786; called by muse, varscan2
- PGM5 | c.1427C>T p.T476M | Missense Mutation (SNP) | VAF 192/568 reads (34%) | SIFT deleterious (0.03); PolyPhen benign (0.336); catalogued as rs200812025; called by muse, varscan2
- PGR | c.1831G>A p.V611I | Missense Mutation (SNP) | VAF 180/379 reads (47%) | SIFT tolerated (0.52); PolyPhen possibly damaging (0.742); catalogued as rs749564230, COSV99677589; called by muse, mutect2, varscan2
- PKD1 | c.11135G>A p.R3712Q (on ENST00000262304 / NM_001009944.3; = p.R3711Q on NM_000296.4) | Missense Mutation (SNP) | VAF 189/407 reads (46%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as rs144624467; called by muse, mutect2, varscan2
- PRDM9 | c.2512G>T p.G838W | Missense Mutation (SNP) | VAF 206/782 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1212449977, COSV57006802; called by muse, mutect2, varscan2
- PRRT4 | c.1682C>T p.A561V | Missense Mutation (SNP) | VAF 341/957 reads (36%) | SIFT tolerated (0.26); PolyPhen benign (0.115); catalogued as rs986573221; called by muse, mutect2, varscan2
- PTPRM | c.2597C>T p.P866L | Missense Mutation (SNP) | VAF 840/1534 reads (55%) | SIFT tolerated (0.61); PolyPhen benign (0.011); catalogued as rs367853227, COSV59857296; called by muse, mutect2, varscan2
- PTPRQ | c.1609C>G p.H537D (on ENST00000616559; = p.H495D on NM_001145026.2) | Missense Mutation (SNP) | VAF 162/328 reads (49%) | SIFT tolerated (0.22); PolyPhen benign (0.003); catalogued as COSV99030935; called by muse, mutect2, varscan2
- RECQL | c.643C>T p.R215* | Nonsense Mutation (SNP) | VAF 339/530 reads (64%) | catalogued as rs376839517, CM155199, COSV59085001; called by muse, mutect2, varscan2
- RHOXF2B | c.529G>A p.A177T | Missense Mutation (SNP) | VAF 4/10 reads (40%) | SIFT tolerated (0.37); PolyPhen benign (0.098); catalogued as rs1157142630; called by mutect2, varscan2
- RNF126 | c.547G>A p.A183T | Missense Mutation (SNP) | VAF 191/435 reads (44%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.492); catalogued as rs866241374, COSV52777670; called by muse, mutect2, varscan2
- SEPTIN12 | c.661G>A p.D221N | Missense Mutation (SNP) | VAF 179/414 reads (43%) | SIFT tolerated (0.32); PolyPhen benign (0.044); catalogued as rs369327426; called by muse, mutect2, varscan2
- SLC16A2 | c.955C>T p.R319C | Missense Mutation (SNP) | VAF 446/450 reads (99%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.959); catalogued as rs1375705723; called by muse, mutect2, varscan2
- SLC9A3 | c.2068-5C>T | Splice Region (SNP) | VAF 144/435 reads (33%) | catalogued as rs773708622; called by muse, mutect2, varscan2
- SNTG2 | c.127A>T p.I43F | Missense Mutation (SNP) | VAF 154/738 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.216); catalogued as rs1558379741; called by muse, mutect2, varscan2
- SORCS1 | c.1304C>T p.T435M | Missense Mutation (SNP) | VAF 167/591 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as rs368458074; called by muse, mutect2, varscan2
- SPAG11B | c.62-2A>G p.X21_splice | Splice Site (SNP) | VAF 114/766 reads (15%) | catalogued as rs771318313; called by muse, varscan2
- TDRD15 | c.4574T>C p.L1525P | Missense Mutation (SNP) | VAF 104/347 reads (30%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV68267607; called by muse, varscan2
- THOP1 | c.751-8G>A | Splice Region (SNP) | VAF 313/319 reads (98%) | catalogued as rs1252019916; called by muse, mutect2, varscan2
- TMEM170B | c.188G>A p.R63K | Missense Mutation (SNP) | VAF 171/410 reads (42%) | SIFT tolerated (0.62); PolyPhen probably damaging (0.982); catalogued as rs1465534575; called by muse, mutect2, varscan2
- TRMT9B | c.107G>A p.R36H | Missense Mutation (SNP) | VAF 293/659 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs375051052; called by muse, mutect2, varscan2
- TRPC4AP | c.14C>T p.P5L | Missense Mutation (SNP) | VAF 269/905 reads (30%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.012); catalogued as rs893100286, COSV52677477, COSV99328745; called by muse, mutect2, varscan2
- TTYH3 | c.1480C>T p.R494C | Missense Mutation (SNP) | VAF 625/840 reads (74%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs751600726; called by muse, varscan2
- ZBBX | c.598G>T p.E200* | Nonsense Mutation (SNP) | VAF 132/317 reads (42%) | catalogued as COSV100284637; called by muse, mutect2, varscan2
- ZNF567 | c.980A>G p.H327R (on ENST00000536254 / NM_001322913.1; = p.H296R on NM_152603.5 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 175/711 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs767087001; called by muse, mutect2, varscan2
- ZNF765 | c.778C>T p.R260C | Missense Mutation (SNP) | VAF 138/651 reads (21%) | SIFT tolerated (0.19); PolyPhen benign (0.003); catalogued as rs201509403; called by muse, mutect2, varscan2
- A2M | c.402C>G p.D134E | Missense Mutation (SNP) | VAF 251/392 reads (64%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ABCA13 | c.12659T>A p.L4220Q | Missense Mutation (SNP) | VAF 243/1139 reads (21%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.824); called by muse, mutect2, varscan2
- ADGRB3 | c.3169A>C p.K1057Q | Missense Mutation (SNP) | VAF 97/248 reads (39%) | SIFT deleterious (0.01); PolyPhen benign (0.192); called by muse, mutect2, varscan2
- AEBP1 | c.563G>T p.S188I | Missense Mutation (SNP) | VAF 173/663 reads (26%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0); called by muse, mutect2, varscan2
- ALK | c.864G>A p.W288* | Nonsense Mutation (SNP) | VAF 218/784 reads (28%) | called by muse, varscan2
- ANKRD18B | c.107G>A p.R36Q | Missense Mutation (SNP) | VAF 448/713 reads (63%) | SIFT tolerated (0.32); PolyPhen benign (0.234); called by muse, mutect2, varscan2
- ARHGAP20 | c.2677A>C p.M893L | Missense Mutation (SNP) | VAF 16/499 reads (3%) | SIFT tolerated (0.4); PolyPhen benign (0); called by muse, mutect2
- BANF1 | c.28T>G p.F10V | Missense Mutation (SNP) | VAF 161/382 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.737); called by muse, mutect2, varscan2
- CC2D2A | c.1131dup p.E378* | Frame Shift Ins (INS) | VAF 90/248 reads (36%) | called by pindel, varscan2
- CFAP47 | c.205C>T p.R69C | Missense Mutation (SNP) | VAF 87/201 reads (43%) | SIFT deleterious (0.02); PolyPhen benign (0.388); called by muse, mutect2, varscan2
- COL21A1 | c.1755C>A p.F585L | Missense Mutation (SNP) | VAF 92/209 reads (44%) | SIFT tolerated (0.67); PolyPhen benign (0); called by muse, mutect2, varscan2
- CUX1 | c.1763A>G p.E588G | Missense Mutation (SNP) | VAF 173/645 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- DOCK3 | c.2930T>A p.L977Q | Missense Mutation (SNP) | VAF 145/348 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); called by muse, mutect2, varscan2
- EGFLAM | c.1294C>A p.H432N | Missense Mutation (SNP) | VAF 162/550 reads (29%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.585); called by muse, mutect2, varscan2
- EIF3A | c.252del p.K84Nfs*11 | Frame Shift Del (DEL) | VAF 77/302 reads (25%) | called by mutect2, pindel, varscan2
- ENTPD2 | c.1285G>A p.A429T (on ENST00000355097 / NM_203468.3; = p.A406T on NM_001246.4) | Missense Mutation (SNP) | VAF 333/515 reads (65%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.837); called by muse, mutect2, varscan2
- EYS | c.4753A>G p.T1585A | Missense Mutation (SNP) | VAF 187/378 reads (49%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.033); called by muse, mutect2, varscan2
- FGFR1 | c.1190A>G p.Y397C (on ENST00000447712 / NM_023110.3; = p.Y395C on NM_015850.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 224/464 reads (48%) | SIFT tolerated (1); PolyPhen benign (0.001); called by muse, varscan2
- FOXF2 | c.143C>T p.S48F | Missense Mutation (SNP) | VAF 164/372 reads (44%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.502); called by muse, mutect2, varscan2
- GRIA1 | c.1067A>G p.N356S | Missense Mutation (SNP) | VAF 184/576 reads (32%) | SIFT tolerated (0.06); PolyPhen benign (0.02); called by muse, varscan2
- HIVEP3 | c.440C>A p.S147Y | Missense Mutation (SNP) | VAF 218/496 reads (44%) | SIFT deleterious (0.01); PolyPhen benign (0.34); called by muse, mutect2, varscan2
- IGSF21 | c.760C>A p.P254T | Missense Mutation (SNP) | VAF 322/644 reads (50%) | SIFT deleterious (0.05); PolyPhen benign (0.137); called by muse, mutect2, varscan2
- ITGAE | c.119C>T p.S40F | Missense Mutation (SNP) | VAF 157/328 reads (48%) | SIFT deleterious (0); PolyPhen possibly damaging (0.564); called by muse, varscan2
- JKAMP | c.185C>G p.P62R (on ENST00000554271 / NM_001284201.1; = p.P48R on NM_016475.5 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 356/360 reads (99%) | SIFT tolerated (0.51); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- KCNH3 | c.415C>T p.R139* | Nonsense Mutation (SNP) | VAF 307/398 reads (77%) | called by muse, varscan2
- KIDINS220 | c.2974A>G p.I992V | Missense Mutation (SNP) | VAF 202/455 reads (44%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- LAMP2 | c.918dup p.N307* | Frame Shift Ins (INS) | VAF 49/181 reads (27%) | called by mutect2, pindel, varscan2
- LAMP2 | c.912T>A p.Y304* | Nonsense Mutation (SNP) | VAF 77/275 reads (28%) | called by muse, mutect2, varscan2
- LAMP2 | c.911A>T p.Y304F | Missense Mutation (SNP) | VAF 77/276 reads (28%) | SIFT tolerated (0.68); PolyPhen benign (0.157); called by muse, mutect2, varscan2
- MFAP3 | c.770A>G p.E257G | Missense Mutation (SNP) | VAF 162/458 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); called by muse, mutect2, varscan2
- MIA3 | c.2826C>G p.Y942* | Nonsense Mutation (SNP) | VAF 137/305 reads (45%) | called by muse, mutect2, varscan2
- MIB2 | c.2776G>A p.G926R | Missense Mutation (SNP) | VAF 223/470 reads (47%) | SIFT tolerated (0.36); PolyPhen possibly damaging (0.691); called by muse, mutect2, varscan2
- MNAT1 | c.353C>G p.T118S | Missense Mutation (SNP) | VAF 86/206 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- MTSS1 | c.823A>C p.S275R | Missense Mutation (SNP) | VAF 125/297 reads (42%) | SIFT tolerated (0.07); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- MUC4 | c.8675G>T p.G2892V | Missense Mutation (SNP) | VAF 326/1702 reads (19%) | SIFT tolerated, low confidence (0.05); PolyPhen probably damaging (0.955); called by muse, varscan2
- MYO1A | c.2123A>G p.Y708C | Missense Mutation (SNP) | VAF 170/445 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); called by muse, mutect2, varscan2
- NAA15 | c.181A>G p.K61E | Missense Mutation (SNP) | VAF 135/319 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.858); called by muse, mutect2, varscan2
- NHSL1 | c.2274del p.N759Mfs*115 | Frame Shift Del (DEL) | VAF 171/397 reads (43%) | called by mutect2, pindel, varscan2
- NRF1 | c.1267T>G p.L423V | Missense Mutation (SNP) | VAF 137/426 reads (32%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.931); called by muse, varscan2
- OAS2 | c.1987T>G p.W663G | Missense Mutation (SNP) | VAF 146/426 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, varscan2
- OGFRL1 | c.459C>A p.H153Q | Missense Mutation (SNP) | VAF 79/281 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- P2RY10 | c.610C>A p.L204I | Missense Mutation (SNP) | VAF 131/325 reads (40%) | SIFT deleterious (0.03); PolyPhen benign (0.26); called by muse, mutect2, varscan2
- PCDH15 | c.5104C>A p.P1702T | Missense Mutation (SNP) | VAF 89/496 reads (18%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.211); called by muse, mutect2, varscan2
- PCDHGB5 | c.427A>C p.S143R | Missense Mutation (SNP) | VAF 166/632 reads (26%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.752); called by muse, mutect2, varscan2
- PCNX1 | c.6388T>G p.C2130G | Missense Mutation (SNP) | VAF 235/543 reads (43%) | SIFT tolerated (0.33); PolyPhen benign (0.043); called by muse, mutect2, varscan2
- PLAA | c.1357G>T p.D453Y | Missense Mutation (SNP) | VAF 113/444 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); called by muse, mutect2, varscan2
- PLOD2 | c.339C>A p.C113* | Nonsense Mutation (SNP) | VAF 135/258 reads (52%) | called by muse, mutect2, varscan2
- POTEG | c.1109C>A p.S370Y | Missense Mutation (SNP) | VAF 58/519 reads (11%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.996); called by muse, mutect2
- PROS1 | c.1076T>G p.I359S | Missense Mutation (SNP) | VAF 167/380 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.8); called by muse, mutect2, varscan2
- RBM46 | c.7G>T p.E3* | Nonsense Mutation (SNP) | VAF 68/178 reads (38%) | called by muse, mutect2, varscan2
- RHD | c.344T>A p.L115Q | Missense Mutation (SNP) | VAF 194/194 reads (100%) | SIFT tolerated (0.55); PolyPhen benign (0.139); called by muse, varscan2
- SALL1 | c.2978G>C p.R993T | Missense Mutation (SNP) | VAF 121/397 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- SHARPIN | c.928G>A p.G310R | Missense Mutation (SNP) | VAF 168/362 reads (46%) | SIFT tolerated (0.4); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SIAH3 | c.610G>T p.E204* | Nonsense Mutation (SNP) | VAF 221/462 reads (48%) | called by muse, mutect2, varscan2
- SKIV2L | c.1702C>T p.P568S | Missense Mutation (SNP) | VAF 288/627 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SLC27A2 | c.92G>T p.G31V | Missense Mutation (SNP) | VAF 166/811 reads (20%) | SIFT tolerated (0.5); PolyPhen benign (0); called by muse, mutect2, varscan2
- SMAD2 | c.1311G>T p.W437C | Missense Mutation (SNP) | VAF 131/131 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SMC1B | c.571A>T p.N191Y | Missense Mutation (SNP) | VAF 178/361 reads (49%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.776); called by muse, mutect2, varscan2
- SORBS1 | c.1930_1942del p.E644Rfs*14 (on ENST00000361941 / NM_001034954.2; = p.E350Rfs*14 on NM_006434.3 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 34/287 reads (12%) | called by mutect2, pindel, varscan2
- SPAG11B | c.62-1G>T p.X21_splice | Splice Site (SNP) | VAF 115/768 reads (15%) | called by muse, varscan2
- SSTR1 | c.314A>G p.E105G | Missense Mutation (SNP) | VAF 258/556 reads (46%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.457); called by muse, mutect2, varscan2
- SSX2IP | c.399T>G p.H133Q | Missense Mutation (SNP) | VAF 107/222 reads (48%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.764); called by muse, mutect2, varscan2
- STK39 | c.960A>T p.K320N | Missense Mutation (SNP) | VAF 100/230 reads (43%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- TAF1L | c.5350A>C p.N1784H | Missense Mutation (SNP) | VAF 268/749 reads (36%) | SIFT tolerated, low confidence (0.08); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- TAF7 | c.703G>C p.E235Q | Missense Mutation (SNP) | VAF 154/507 reads (30%) | SIFT tolerated (0.05); PolyPhen benign (0.261); called by muse, mutect2, varscan2
- TG | c.2348A>G p.E783G | Missense Mutation (SNP) | VAF 219/463 reads (47%) | SIFT deleterious (0); PolyPhen benign (0.245); called by muse, mutect2, varscan2
- THOC3 | c.309C>G p.D103E | Missense Mutation (SNP) | VAF 14/50 reads (28%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.958); called by mutect2, varscan2
- TMPO | c.349_366del p.N117_D122del | In Frame Del (DEL) | VAF 33/172 reads (19%) | called by mutect2, pindel, varscan2
- TMTC1 | c.200C>T p.A67V | Missense Mutation (SNP) | VAF 233/1110 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.025); called by muse, mutect2, varscan2
- TRIM61 | c.276A>C p.E92D | Missense Mutation (SNP) | VAF 116/324 reads (36%) | SIFT tolerated (0.06); PolyPhen benign (0.261); called by muse, mutect2, varscan2
- TTN | c.56064G>T p.K18688N (on ENST00000591111; = p.K11264N on NM_003319.4) | Missense Mutation (SNP) | VAF 128/380 reads (34%) | PolyPhen benign (0.372); called by muse, mutect2, varscan2
- UBR2 | c.4624C>T p.H1542Y | Missense Mutation (SNP) | VAF 12/338 reads (4%) | SIFT deleterious (0); PolyPhen benign (0.035); called by muse, mutect2
- UNC50 | c.44G>C p.G15A | Missense Mutation (SNP) | VAF 353/580 reads (61%) | SIFT tolerated (0.13); PolyPhen benign (0.142); called by muse, mutect2, varscan2
- YTHDC2 | c.1359+1del | Frame Shift Del (DEL) | VAF 52/197 reads (26%) | called by mutect2, pindel, varscan2
- ZFYVE28 | c.949_962delinsCT p.E317_S321delinsL | In Frame Del (DEL) | VAF 115/307 reads (37%) | called by pindel, varscan2*
- ZNF407 | c.859_876del p.Q287_K292del | In Frame Del (DEL) | VAF 68/88 reads (77%) | called by pindel, varscan2
- ANK3 | c.12111G>A p.S4037= | Silent (SNP) | VAF 188/666 reads (28%) | catalogued as rs557280144, COSV55090361; called by muse, varscan2
- ANKRD34A | c.303C>T p.G101= | Silent (SNP) | VAF 380/728 reads (52%) | catalogued as rs1173022118; called by muse, mutect2, varscan2
- APOB | c.2118G>A p.G706= | Silent (SNP) | VAF 256/701 reads (37%) | catalogued as rs1159654255, COSV51952270; called by muse, varscan2
- BPNT1 | c.705T>G p.A235= | Silent (SNP) | VAF 166/365 reads (45%) | called by muse, mutect2, varscan2
- CC2D1A | c.588C>T p.A196= | Silent (SNP) | VAF 22/596 reads (4%) | called by muse, mutect2
- CCDC141 | c.3342C>G p.L1114= | Silent (SNP) | VAF 105/267 reads (39%) | called by muse, mutect2, varscan2
- CDH2 | c.1536C>A p.A512= | Silent (SNP) | VAF 129/570 reads (23%) | called by muse, mutect2, varscan2
- COL22A1 | c.4491C>A p.G1497= | Silent (SNP) | VAF 180/402 reads (45%) | called by muse, mutect2, varscan2
- CSNK1G2 | c.741C>T p.R247= | Silent (SNP) | VAF 281/584 reads (48%) | catalogued as rs373599985; called by muse, mutect2, varscan2
- CYP2U1 | c.354C>T p.F118= | Silent (SNP) | VAF 256/545 reads (47%) | called by muse, mutect2, varscan2
- CYRIA | c.582G>A p.T194= | Silent (SNP) | VAF 145/453 reads (32%) | catalogued as rs753862688, COSV62866917; called by muse, mutect2, varscan2
- DDC | c.1410G>T p.L470= | Silent (SNP) | VAF 289/665 reads (43%) | called by muse, mutect2, varscan2
- ERICH6B | c.1371A>G p.L457= | Silent (SNP) | VAF 142/324 reads (44%) | called by muse, mutect2, varscan2
- FLG | c.4365C>T p.H1455= | Silent (SNP) | VAF 173/401 reads (43%) | catalogued as rs142950612; called by muse, mutect2, varscan2
- GFPT2 | c.912T>C p.S304= | Silent (SNP) | VAF 162/594 reads (27%) | called by muse, mutect2, varscan2
- GLI3 | c.3066G>A p.P1022= | Silent (SNP) | VAF 1017/1354 reads (75%) | catalogued as rs1206623585, COSV67885002; called by muse, mutect2, varscan2
- GPRC6A | c.504T>C p.G168= | Silent (SNP) | VAF 110/282 reads (39%) | called by muse, mutect2, varscan2
- HRH3 | c.990G>A p.S330= | Silent (SNP) | VAF 603/892 reads (68%) | catalogued as rs199993900; called by muse, varscan2
- HSPA12B | c.1275C>T p.N425= | Silent (SNP) | VAF 369/757 reads (49%) | catalogued as rs776009719; called by muse, mutect2, varscan2
- HTR6 | c.430C>T p.L144= | Silent (SNP) | VAF 348/746 reads (47%) | called by muse, mutect2, varscan2
- IQGAP2 | c.957C>T p.P319= | Silent (SNP) | VAF 158/559 reads (28%) | catalogued as rs781281584, COSV99169248; called by muse, mutect2, varscan2
- KCNG2 | c.186C>T p.Y62= | Silent (SNP) | VAF 379/379 reads (100%) | called by muse, mutect2, varscan2
- KLF4 | c.1080C>A p.V360= | Silent (SNP) | VAF 317/532 reads (60%) | called by muse, mutect2, varscan2
- LYAR | c.519A>G p.K173= | Silent (SNP) | VAF 417/420 reads (99%) | called by muse, mutect2, varscan2
- MAB21L1 | c.585G>A p.P195= | Silent (SNP) | VAF 171/381 reads (45%) | catalogued as rs368588802; called by muse, mutect2, varscan2
- MAGEB6B | c.945G>A p.G315= | Silent (SNP) | VAF 175/473 reads (37%) | called by muse, mutect2, varscan2
- MAGEL2 | c.534G>T p.P178= | Silent (SNP) | VAF 811/1333 reads (61%) | called by muse, mutect2, varscan2
- MFF | c.606G>A p.S202= | Silent (SNP) | VAF 107/286 reads (37%) | catalogued as rs555978161, COSV58825984; called by muse, mutect2, varscan2
- MTERF3 | c.993C>T p.T331= | Silent (SNP) | VAF 290/290 reads (100%) | catalogued as rs758644998, COSV54635141; called by muse, mutect2, varscan2
- NLRP5 | c.1776C>A p.A592= | Silent (SNP) | VAF 181/854 reads (21%) | catalogued as COSV66763646; called by muse, mutect2, varscan2
- NT5DC4 | c.1002T>A p.T334= | Silent (SNP) | VAF 240/748 reads (32%) | called by muse, varscan2
- OR11G2 | c.882G>T p.L294= | Silent (SNP) | VAF 146/338 reads (43%) | called by muse, mutect2, varscan2
- OSTF1 | c.324T>C p.T108= | Silent (SNP) | VAF 150/488 reads (31%) | called by muse, varscan2
- PCDHA2 | c.1335G>T p.V445= | Silent (SNP) | VAF 241/688 reads (35%) | called by muse, mutect2, varscan2
- PCDHGA3 | c.1935C>T p.A645= | Silent (SNP) | VAF 126/1750 reads (7%) | catalogued as COSV53898074; called by muse, mutect2
- PCDHGA8 | c.1935C>T p.A645= | Silent (SNP) | VAF 545/845 reads (64%) | called by muse, mutect2, varscan2
- PIWIL1 | c.144C>T p.G48= | Silent (SNP) | VAF 217/495 reads (44%) | called by muse, mutect2, varscan2
- PLEKHF1 | c.810G>A p.S270= | Silent (SNP) | VAF 447/914 reads (49%) | catalogued as rs373551601; called by muse, varscan2
- PRDM9 | c.363G>A p.K121= | Silent (SNP) | VAF 76/281 reads (27%) | called by muse, mutect2, varscan2
- SERPINA6 | c.78C>T p.N26= | Silent (SNP) | VAF 460/464 reads (99%) | catalogued as rs758471605; called by muse, mutect2, varscan2
- SGSM1 | c.1068C>T p.G356= | Silent (SNP) | VAF 285/592 reads (48%) | catalogued as rs371807192; called by muse, mutect2, varscan2
- SH3BP4 | c.249C>T p.Y83= | Silent (SNP) | VAF 228/453 reads (50%) | catalogued as rs778110762; called by muse, mutect2, varscan2
- SNRNP200 | c.2490C>T p.G830= | Silent (SNP) | VAF 115/416 reads (28%) | called by muse, mutect2, varscan2
- SPATA31A6 | c.2265G>A p.Q755= | Silent (SNP) | VAF 16/17 reads (94%) | catalogued as rs1458571466; called by mutect2, varscan2
- TENM2 | c.1455C>T p.L485= (on ENST00000518659 / NM_001122679.2; = p.L253= on NM_001080428.3) | Silent (SNP) | VAF 174/568 reads (31%) | catalogued as rs773074265, COSV69146539; called by muse, mutect2, varscan2
- TRAPPC9 | c.300C>T p.H100= | Silent (SNP) | VAF 201/414 reads (49%) | catalogued as rs200067455; called by muse, mutect2, varscan2
- TRIOBP | c.5742C>T p.G1914= (on ENST00000644935 / NM_001039141.3; = p.G201= on NM_007032.5) | Silent (SNP) | VAF 57/531 reads (11%) | called by muse, mutect2, varscan2
- ZNF20 | c.1164G>A p.T388= | Silent (SNP) | VAF 198/494 reads (40%) | catalogued as rs745920069, COSV61998713; called by muse, mutect2, varscan2
- ZNF550 | c.420G>C p.V140= | Silent (SNP) | VAF 439/913 reads (48%) | called by muse, mutect2, varscan2
- ADAM33 | c.333+42A>C | Intron (SNP) | VAF 71/483 reads (15%) | called by muse, mutect2, varscan2
- CCDC103 | c.277-18C>A | Intron (SNP) | VAF 138/449 reads (31%) | called by muse, mutect2, varscan2
- GOLGA8K | c.48+101T>G | Intron (SNP) | VAF 141/144 reads (98%) | called by muse, mutect2, varscan2
- GPR141 | chr7:37740393 T>A | 5'Flank (SNP) | VAF 191/322 reads (59%) | called by muse, mutect2, varscan2
- IGKV1-5 | c.-20A>C | 5'UTR (SNP) | VAF 238/700 reads (34%) | catalogued as rs780015776; called by muse, mutect2, varscan2
- LIMK1 | c.-32_-28del | 5'UTR (DEL) | VAF 63/71 reads (89%) | called by mutect2, pindel, varscan2
- MFSD4B | c.27+2595C>A | Intron (SNP) | VAF 209/460 reads (45%) | catalogued as rs770452076; called by muse, varscan2
- NAIPP4 | n.508T>A | RNA (SNP) | VAF 49/401 reads (12%) | called by muse, varscan2
- PRKRIP1 | c.-652G>T | 5'UTR (SNP) | VAF 91/368 reads (25%) | catalogued as COSV101461530; called by muse, mutect2, varscan2
- RIPOR2 | c.-105G>A | 5'UTR (SNP) | VAF 110/225 reads (49%) | catalogued as COSV73375358; called by muse, mutect2, varscan2
- RPL37AP1 | chr20:44462219 C>T | 3'Flank (SNP) | VAF 187/645 reads (29%) | called by muse, mutect2, varscan2
- SNRPC | c.9-10del | Intron (DEL) | VAF 110/362 reads (30%) | called by pindel, varscan2
- STARD8 | c.-162C>A | 5'UTR (SNP) | VAF 152/396 reads (38%) | called by muse, mutect2, varscan2
- TPCN1 | c.-3A>C | 5'UTR (SNP) | VAF 196/425 reads (46%) | called by muse, mutect2, varscan2
- VAT1L | c.-6A>T | 5'UTR (SNP) | VAF 13/379 reads (3%) | called by muse, mutect2
- WDPCP | c.385-45C>A | Intron (SNP) | VAF 48/216 reads (22%) | called by muse, varscan2
- WDR45 | c.*102G>C | 3'UTR (SNP) | VAF 29/254 reads (11%) | catalogued as rs943051326, COSV59876297; called by muse, mutect2
